Somatic mutation profile of tumor specimen 0DRB5N from CCDI case PBCGFX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,300 days).
Specimen 0DRB5N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f56cdc7-e42a-4084-89c2-6655d99de686.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e473679a-8d6e-44c5-b764-482172f5273c

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 3'UTR 1, RNA 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.3040G>A p.G1014S | Missense Mutation (SNP) | VAF 51/1472 reads (3%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.068); called by muse, mutect2
- GCKR | c.1320C>T p.T440= | Silent (SNP) | VAF 194/676 reads (29%) | catalogued as rs140472515; called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/458 reads (4%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 20/200 reads (10%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
